Gene-level copy-number profile of tumor specimen TARGET-10-PAMXHJ-09A from TARGET case TARGET-10-PAMXHJ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.1 years (2,219 days).
Specimen TARGET-10-PAMXHJ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.b55b0593-7f96-56b3-a6bb-a7cc7f757572.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PAMXHJ-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 356 have no estimate.
https://portal.gdc.cancer.gov/files/89ec1554-9fe9-43c9-9d37-287a49e3cdb0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 215; copy number 2: 34,183; copy number 3: 20,113; copy number 4: 5,635; copy number 5: 24; copy number 6: 35; copy number 7: 60.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,614,098, 2 genes: LCE3C, LCE3B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 111 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,301,472–72,301,829, 1 gene, copy number 5: RPL31P12.
- chr4:96,310,701–96,818,864, 1 gene, copy number 5 (within-gene range 3–5): LINC02267.
- chr16:52,934,813–56,357,444, 77 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr16:61,638,233–63,936,906, 20 genes, copy number 6: AC092125.2, CDH8, AC092125.1, RN7SKP76, AC012174.1, RNU6-21P, AC009161.2, AC009161.1, AC009110.1, AC010546.1, AC040174.1, AC040174.2, UBE2FP2, AC138305.1, RPS15AP34, AC138305.2, AC138305.3, AC018846.1, LINC02165, AC092337.1.
- chr20:7,255,053–8,043,512, 10 genes, copy number 5: AL080248.1, LINC01751, LINC01706, MIR8062, RN7SL547P, AL031679.1, AL021879.1, HAO1, TMX4, AL021396.1.
- chr20:8,097,824–8,256,918, 2 genes, copy number 5: PHKBP1, PLCB1-IT1.

Autosomal genes at a single copy (total copy number 1): 215. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
